CCDI case PBBNCU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1640cc88-df9f-423c-aeb7-84460b8df97a

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.1 years (776 days).

Biospecimens (3 samples)
- Sample 0DCXAA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCXAJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCXBB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
